Surgical pathology report (de-identified scan), TCGA case TCGA-10-0936, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-10-0936-01A (Primary Tumor).

- [REDACTED]
- (A) PORTION OF OMENTUM:
METASTATIC HIGH-GRADE PAPILLARY SEROUS CARCINOMA.
- (B) RIGHT TUBE AND OVARY:
OVARIAN HIGH-GRADE PAPILLARY SEROUS CARCINOMA EXTENDING TO PERIADNEXAL SOFT TISSUE AND TO THE FALLOPIAN TUBE SURFACE, WALL AND FIMBRIATED END.
- (C) LEFT TUBE AND OVARY:
OVARIAN HIGH-GRADE PAPILLARY SEROUS CARCINOMA EXTENDING FOCALLY TO THE FALLOPIAN TUBE SURFACE WITH DETACHED TUMOR CLUSTERS IN THE FALLOPIAN TUBE LUMEN.
- (D) UTERUS AND CERVIX:
METASTATIC HIGH-GRADE PAPILLARY SEROUS CARCINOMA, UTERINE SEROSA.
Inactive endometrium.
Adenomyosis.
Nabothian cysts, mild chronic inflammation and squamous metaplasia, cervix.
- (E) UMBILICUS:
METASTATIC HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVOLVING SUBCUTANEOUS TISSUE AND DERMIS.
- [REDACTED]

GROSS DESCRIPTION

- (A) PORTION OF OMENTUM - A portion of omentum (9.5 x 8.5 x 3.5 cm) infiltrated by firm, white tumor.
SECTION CODE: A1, A2, representative omentum for frozen section; A3-A5, representative omentum [REDACTED]
*FS/DX: HIGH-GRADE CARCINOMA CONSISTENT WITH MULLERIAN PRIMARY. [REDACTED]
- (B) RIGHT TUBE AND OVARY - A cystic ovary (10.0 x 7.0 x 4.5 cm) with attached fallopian tube (3.5 x 0.8 x 0.4 cm) and periadnexal soft tissue (4.8 x 0.8 x 0.4 cm).
The ovarian cyst is filled with clear fluid and is lined by fleshy pink tumor. The ovarian surface has a focal, roughened area, which may represent papillary excrescences (2.0 x 1.0 cm). The remaining ovarian surface is white and smooth. Tumor is adjacent to the fallopian tube without gross evidence of invasion into the fallopian tube wall.
INK CODE: Black - outer surface of ovary.
SECTION CODE: B1, B2, entire fallopian tube; B3-B9, representative cyst wall with tumor (rough area on ovarian surface entirely in B9); B10, representative periadnexal soft tissue. [REDACTED]
- (C) LEFT TUBE AND OVARY - An ovary (7.5 x 3.0 x 3.0 cm) and fallopian tube (2.7 x 0.6 x 0.5 cm).
The ovary is nearly completely replaced by friable, tan tumor. The tumor is adjacent to the fallopian tube without gross evidence of invasion into the fallopian tube wall.
SECTION CODE: C1, entire fallopian tube; C2-C8, representative ovarian tumor. [REDACTED]
- (D) UTERUS AND CERVIX - A uterus (7.5 x 4.5 x 2.8 cm) and unremarkable cervix (3.3 x 2.9 cm).
The posterior serosa is roughened, suspicious for involvement by tumor. The endometrium (0.1 cm thick) is smooth and unremarkable. The myometrium (1.7 cm thick) is unremarkable.
SECTION CODE: D1, posterior serosa; D2, cervix, 12 o'clock; D3, cervix, 6 o'clock; D4, anterior endomyometrium; D5, posterior endomyometrium. [REDACTED]
- (E) UMBILICUS - An unoriented skin ellipse (6.8 x 2.8 x 2.5 cm) with a raised, subcutaneous, tan, friable, central nodule (1.1 x 1.0 x 1.0 cm).

Source: NCI Genomic Data Commons file 8414c673-a2c0-47be-bdf7-35dff97860c0 (TCGA-10-0936.6B9A13E4-760E-476F-A0A7-FB42AB7C63C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).